Surgical pathology report (de-identified scan), TCGA case TCGA-EE-A3AH, project TCGA-SKCM (Skin Cutaneous Melanoma), tissue source site University of Sydney, specimen TCGA-EE-A3AH-06A (Metastatic).

[page 1 of 2]
N/A
N/A
N/A
N/A
N/A N/A N/A

DOB/Age/Sex:
Location:
Requested by:
Requested on:
Specimen Rcvd:
Accession No.:
Copies to:

HISTOPATHOLOGY SUPPLEMENTARY REPORT

SUPPLEMENTARY REPORT

Right groin, lymph node dissection

The extranodal spread spans a distance of ~2mm.

SUPPLEMENTARY SUMMARY

Right groin, lymph node dissection

Please see above and previous report.

REPORTED BY: Dr

1CB-0-3

Melanoma, NOS 8720/3

Site: lymph node, groin

C 77.4

hw 9/21/11

HISTOPATHOLOGY REPORT

REFERRED MRN

CLINICAL DETAILS

Right groin dissection. Right groin contents long tie upper.

MACROSCOPIC DESCRIPTION

(Dr

"RIGHT GROIN CONTENTS LONG TIE UPPER". An elongated piece of fibrofatty tissue 230 x 60 x 40mm, with a narrow ellipse of overlying skin 20 x 25mm. An "upper" marking suture is present at one end of the skin ellipse. The specimen dissected from upper and towards the lower ends and blocks are taken in this order. The cut surface reveals multiple enlarged lymph nodes in the fatty tissue. The largest node has a black surface and measures 15 x 10 x 12mm in the central portion. Tissue for tumour banking was taken from the largest node at the fresh state.

- A. 4 nodes.
- B. One full face transverse section of the second largest node 14mm across.
- C. 4 nodes.
- D. 3 nodes.
- E. The largest node, representative section.
- F. 3 nodes.
- G. 4 nodes
- H. 1 node
- J. 1 node bisected.
- K. 1 node.

MICROSCOPIC REPORT

Right groin, lymph node dissection

Diagnosis: metastatic melanoma

[page 2 of 2]
Requested by:

MRN/Name:

Location:

Accession:

HISTOPATHOLOGY REPORT

Number of lymph nodes: identified 23; involved by metastatic melanoma: 6

Location of tumour: extensive

Maximal size of largest tumour deposit: ~15 x 12 x 10mm (macroscopic), accounting for ~95% of the nodal cross-sectional area

Tumour description: pleomorphic, mitotically active, pigmented epithelioid cells with areas of necrosis

Extranodal spread: present (E)

Immunohistochemistry: S-100 positive; HMB-45 positive; Melan-A positive

(Dr

SUMMARY

Right groin, lymph node dissection

Metastatic melanoma in 6 of 23 lymph nodes.

REPORTED BY: Dr

Source: NCI Genomic Data Commons file 242ad376-017a-4cd9-b820-3879b760faf4 (TCGA-EE-A3AH.DDD46A19-CD8A-40EE-91C4-6CB78FAC80DC.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).